Somatic mutation profile of tumor specimen MP2PRT-PAUHWL-TMP1-A (aliquot MP2PRT-PAUHWL-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUHWL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,774 days).
Specimen MP2PRT-PAUHWL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76e5cb24-7216-4f3a-95c0-aaa44febe4e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUHWL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUHWL-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6453043-aeaf-4dd8-ac7d-a5bb030e70d4

The open-access MAF lists 108 somatic variants for this specimen: 84 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 19, Nonsense Mutation 8, Intron 2, 5'Flank 1, Nonstop Mutation 1, 3'Flank 1, In Frame Ins 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 249/574 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACACB | c.3995C>G p.P1332R | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58128096; called by muse, mutect2, varscan2
- ARHGEF5 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 230/2598 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV99283026; called by muse, mutect2
- ASXL3 | c.5992G>A p.E1998K | Missense Mutation (SNP) | VAF 50/669 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.211); catalogued as rs762717568; called by muse, mutect2
- CNTNAP2 | c.1496G>C p.G499A | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62204494; called by muse, mutect2
- DAPK1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 106/253 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63789237; called by muse, mutect2, varscan2
- DHX40 | c.113-1G>C p.X38_splice | Splice Site (SNP) | VAF 82/201 reads (41%) | catalogued as COSV99232812; called by muse, mutect2, varscan2
- EPHB4 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 23/554 reads (4%) | catalogued as rs1452526453, COSV62268558; called by muse, mutect2
- FREM2 | c.2863G>C p.D955H | Missense Mutation (SNP) | VAF 94/269 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs889684853; called by muse, mutect2, varscan2
- FRY | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs753218297; called by muse, mutect2, varscan2
- GABRP | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 24/536 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs750576513, COSV54661964; called by muse, mutect2
- HCAR3 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 49/476 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as COSV63674006; called by muse, mutect2, varscan2
- ITGBL1 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66009937; called by muse, mutect2
- KCND2 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 154/356 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58572065; called by muse, mutect2, varscan2
- KIAA0753 | c.1705C>G p.P569A | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1349814240, COSV63818035; called by muse, mutect2
- LPIN3 | c.1496C>G p.S499C | Missense Mutation (SNP) | VAF 191/464 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV64717299; called by muse, mutect2, varscan2
- MYO7A | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 246/642 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs376169396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 75/535 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NVL | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs1189605352, COSV55873574; called by muse, mutect2, varscan2
- OR10H5 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 53/492 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.082); catalogued as COSV58278121; called by muse, mutect2, varscan2
- PCDH15 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.426); catalogued as rs747154146, COSV57374587; called by muse, mutect2, varscan2
- PCDHA9 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 20/514 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV65324163; called by muse, mutect2
- PDE4A | c.1507G>A p.E503K (on ENST00000380702 / NM_001111307.2; = p.E264K on NM_006202.3) | Missense Mutation (SNP) | VAF 159/431 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53356512, COSV53360736; called by muse, mutect2, varscan2
- PRX | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 37/825 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); catalogued as rs748063094; called by muse, mutect2
- RFX6 | c.2158C>A p.H720N | Missense Mutation (SNP) | VAF 169/476 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV60586740; called by muse, mutect2, varscan2
- RRBP1 | c.1651G>C p.D551H | Missense Mutation (SNP) | VAF 202/588 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); catalogued as rs751492770; called by muse, mutect2, varscan2
- SLC35E1 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 262/612 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as rs989936448; called by muse, mutect2, varscan2
- SNX11 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 256/593 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs550309005; called by muse, mutect2, varscan2
- TNKS2 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 175/459 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.117); catalogued as rs769033982, COSV65415147; called by muse, mutect2, varscan2
- TRAV21 | c.311C>G p.S104* | Nonsense Mutation (SNP) | VAF 94/220 reads (43%) | catalogued as rs34233656; called by muse, mutect2, varscan2
- UBQLN2 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 41/835 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.313); catalogued as COSV57740095; called by muse, mutect2
- USP26 | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 21/425 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as COSV63709114; called by muse, mutect2
- ZDHHC11 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs1396052183; called by muse, mutect2
- ZNF669 | c.1333G>C p.G445R | Missense Mutation (SNP) | VAF 36/588 reads (6%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.201); catalogued as rs1429741149; called by muse, mutect2
- ZNF75D | c.642G>C p.Q214H | Missense Mutation (SNP) | VAF 156/617 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); catalogued as rs782075742, COSV66132713; called by muse, mutect2, varscan2
- ACACA | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 186/501 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM29 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 136/392 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- AMOT | c.1659G>C p.K553N (on ENST00000371959 / NM_001113490.1; = p.K144N on NM_133265.3) | Missense Mutation (SNP) | VAF 28/600 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- BTBD19 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 133/316 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CBX3 | c.311C>G p.S104* | Nonsense Mutation (SNP) | VAF 48/157 reads (31%) | called by muse, mutect2, varscan2
- CCAR1 | c.3452G>C p.*1151Sext*1 | Nonstop Mutation (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- CCDC146 | c.2476G>C p.E826Q | Missense Mutation (SNP) | VAF 114/343 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC150 | c.698C>G p.S233* | Nonsense Mutation (SNP) | VAF 76/211 reads (36%) | called by muse, mutect2, varscan2
- CCDC150 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHM | c.88A>T p.S30C | Missense Mutation (SNP) | VAF 29/494 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.113); called by muse, mutect2
- CNNM1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 31/536 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); called by muse, mutect2
- CNTRL | c.4642C>G p.Q1548E | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- COL4A6 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 14/474 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCP1A | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 153/400 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- DGCR2 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 38/560 reads (7%) | called by muse, mutect2
- DMXL1 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 111/318 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DOP1A | c.2788C>G p.H930D | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- DUSP4 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 152/404 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.083); called by muse, mutect2
- EML5 | c.5858G>A p.G1953E (on ENST00000380664; = p.G1961E on NM_183387.3) | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM184B | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 167/444 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GMNC | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); called by muse, mutect2
- GNAT2 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.857); called by muse, mutect2
- GNG7 | c.186G>C p.K62N | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- GON4L | c.6046G>C p.E2016Q | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- GRM5 | c.967G>C p.G323R | Missense Mutation (SNP) | VAF 21/451 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GTPBP4 | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- IGHV1-3 | c.351_352insCCGGCTAA | In Frame Ins (INS) | VAF 32/59 reads (54%) | called by mutect2, pindel*, varscan2*
- IHH | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 27/648 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- ISCU | c.430G>C p.D144H (on ENST00000311893 / NM_213595.4; = p.D119H on NM_014301.4) | Missense Mutation (SNP) | VAF 145/381 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LHX1 | c.955C>G p.P319A | Missense Mutation (SNP) | VAF 56/1171 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- LIPT2 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 320/838 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, varscan2
- MMRN1 | c.797C>G p.S266* | Nonsense Mutation (SNP) | VAF 94/236 reads (40%) | called by muse, mutect2, varscan2
- MNAT1 | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOGAT3 | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 230/587 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NME5 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2
- NPB | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 60/1092 reads (5%) | called by muse, mutect2
- NPFFR2 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 27/560 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2
- OTUD5 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 114/298 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH7 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 146/368 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1 | c.11689G>A p.E3897K | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- POTEJ | c.2020G>C p.D674H | Missense Mutation (SNP) | VAF 243/910 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- PWWP3A | c.1006G>C p.E336Q (on ENST00000627377; = p.E335Q on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 259/644 reads (40%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SERPINA7 | c.1123C>G p.Q375E | Missense Mutation (SNP) | VAF 53/454 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SIX4 | c.2180C>G p.S727* | Nonsense Mutation (SNP) | VAF 114/330 reads (35%) | called by muse, mutect2, varscan2
- TEX11 | c.1008C>G p.D336E (on ENST00000344304; = p.D321E on NM_031276.3) | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TOGARAM2 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 221/603 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBA6 | c.1352G>C p.G451A | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZFP36 | c.701C>T p.S234L (on ENST00000594442; = p.S228L on NM_003407.5) | Missense Mutation (SNP) | VAF 48/864 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.099); called by muse, mutect2
- ZNF382 | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2
- ACER3 | c.177G>C p.L59= | Silent (SNP) | VAF 137/240 reads (57%) | called by muse, mutect2, varscan2
- CARNS1 | c.1395C>G p.L465= | Silent (SNP) | VAF 36/762 reads (5%) | called by muse, mutect2
- CDKN2AIPNL | c.201C>T p.L67= | Silent (SNP) | VAF 281/679 reads (41%) | called by muse, mutect2, varscan2
- CXCR3 | c.147G>A p.L49= | Silent (SNP) | VAF 42/897 reads (5%) | catalogued as COSV65462371; called by muse, mutect2
- DMRTB1 | c.412C>T p.L138= | Silent (SNP) | VAF 274/765 reads (36%) | catalogued as rs1192357548; called by muse, mutect2, varscan2
- DSCAML1 | c.600C>T p.N200= (on ENST00000321322; = p.N140= on NM_020693.4) | Silent (SNP) | VAF 34/564 reads (6%) | catalogued as rs759797305, COSV58388374; called by muse, mutect2
- DSP | c.1680C>T p.I560= | Silent (SNP) | VAF 127/366 reads (35%) | catalogued as rs397516920; ClinVar: likely benign; called by muse, mutect2, varscan2
- ENY2 | c.99G>A p.L33= | Silent (SNP) | VAF 92/289 reads (32%) | catalogued as COSV99516796; called by muse, mutect2, varscan2
- ITFG1 | c.738C>G p.V246= | Silent (SNP) | VAF 77/247 reads (31%) | catalogued as rs747860268; called by muse, mutect2, varscan2
- KCNMA1 | c.3120C>T p.V1040= (on ENST00000286628 / NM_001161352.2; = p.V982= on NM_002247.4) | Silent (SNP) | VAF 12/339 reads (4%) | called by muse, mutect2
- KRT8 | c.1446C>G p.P482= | Silent (SNP) | VAF 104/277 reads (38%) | catalogued as rs746902650; called by muse, varscan2
- MAP3K5 | c.2454C>T p.L818= | Silent (SNP) | VAF 18/384 reads (5%) | called by muse, mutect2
- MROH2B | c.2151T>G p.L717= | Silent (SNP) | VAF 14/446 reads (3%) | called by muse, mutect2
- NUMA1 | c.4044C>G p.L1348= | Silent (SNP) | VAF 228/554 reads (41%) | catalogued as rs746525513, COSV61190454; called by muse, mutect2, varscan2
- PAPPA | c.4041C>T p.L1347= | Silent (SNP) | VAF 39/768 reads (5%) | catalogued as rs1230651441; called by muse, mutect2
- REXO1 | c.2613C>G p.L871= | Silent (SNP) | VAF 29/590 reads (5%) | called by muse, mutect2
- RRBP1 | c.1428G>A p.Q476= | Silent (SNP) | VAF 155/604 reads (26%) | catalogued as COSV55705959, COSV99854306; called by muse, varscan2
- SPTBN4 | c.2247G>C p.A749= | Silent (SNP) | VAF 342/883 reads (39%) | catalogued as rs1368635926; called by muse, mutect2, varscan2
- TMEM200C | c.1242G>T p.P414= | Silent (SNP) | VAF 296/820 reads (36%) | catalogued as COSV67309798; called by muse, varscan2
- AC244197.3 | c.*2449C>G | 3'UTR (SNP) | VAF 54/574 reads (9%) | called by muse, mutect2
- ARHGEF4 | chr2:130914201 G>A | 5'Flank (SNP) | VAF 107/291 reads (37%) | catalogued as rs558164193, COSV100387934; called by muse, mutect2, varscan2
- IGHV1-3 | chr14:106005094 ins ACGC | 3'Flank (INS) | VAF 28/52 reads (54%) | called by mutect2, varscan2*
- PLCE1 | c.1207-42873C>T | Intron (SNP) | VAF 195/552 reads (35%) | called by muse, mutect2, varscan2
- ZNF606 | c.88+153C>G | Intron (SNP) | VAF 108/332 reads (33%) | catalogued as COSV58351123; called by muse, mutect2, varscan2
